Surgical pathology report (de-identified scan), TCGA case TCGA-DF-A2KV, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Ontario Institute for Cancer Research, specimen TCGA-DF-A2KV-01A (Primary Tumor).

Sample Type TUMOUR

Sample Preparation
Site of Primary (Event)
Site of Tissue
Year of Sample Collection
Age at Sample Collection (yrs)
Sample Comments
Days to Procedure Date
Days to Diagnosis
Type of Procedure
Site of Primary (Histology)
Bilateral Disease
Tumour Size (cm)
Histology
Grade/Differentiation
Pathological T
Pathological N
Number of Nodes Sampled
Number of Nodes Positive
Clinical M
Histology Comments

Fresh Frozen
Uterine
endometrial mass

ICD-0-3
adenocarcinoma, endometrioid, NOS
8380/3
Site: Endometrium C54.1
8/23/11

0
27
Surgical resection
Uterus
UNK
3.7999999999999998
Endometrioid adenocarcinoma, NOS
III
T1b
NO
0
21
N/A

Source: NCI Genomic Data Commons file a93a6983-02cc-4e80-ba22-1e357ceb6eb1 (TCGA-DF-A2KV.5717937B-AC81-452E-9B4D-3301FDA7CD0B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).